Somatic mutation profile of tumor specimen MP2PRT-PARGCH-TMP1-A (aliquot MP2PRT-PARGCH-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARGCH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,741 days).
Specimen MP2PRT-PARGCH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 484ffc34-edb3-424b-8411-b26355944906.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGCH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGCH-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22c37348-fbe4-4a10-968d-5bf6e9c05213

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2516A>G p.D839G | Missense Mutation (SNP) | VAF 18/355 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs991132188, COSV54045448; ClinVar: likely pathogenic; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 127/392 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FREM1 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 162/349 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs539557870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR1A1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 128/294 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs371610534; called by muse, mutect2, varscan2
- POLN | c.2299G>A p.V767M | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as rs749012576, COSV67028402; called by muse, mutect2, varscan2
- CCDC186 | c.460_461del p.K154Efs*15 | Frame Shift Del (DEL) | VAF 111/496 reads (22%) | called by mutect2, pindel, varscan2
- CFAP221 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CTCF | c.1381T>C p.S461P | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- PRPS1 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ACSL5 | c.1053G>A p.V351= (on ENST00000354273; = p.V407= on NM_016234.3) | Silent (SNP) | VAF 23/294 reads (8%) | called by muse, mutect2
- IQSEC3 | c.1209C>T p.T403= (on ENST00000538872 / NM_001170738.2; = p.T100= on NM_015232.1) | Silent (SNP) | VAF 218/481 reads (45%) | catalogued as rs782619341; called by muse, mutect2, varscan2
- NLRP13 | c.2004C>T p.D668= | Silent (SNP) | VAF 183/361 reads (51%) | catalogued as rs140606375; called by muse, mutect2, varscan2
- RGS7 | c.1230C>T p.N410= | Silent (SNP) | VAF 140/468 reads (30%) | catalogued as COSV58535609; called by muse, mutect2, varscan2
